Somatic mutation profile of tumor specimen TARGET-15-SJMPAL040032-09A.1 (aliquot TARGET-15-SJMPAL040032-09A.1-01D) from TARGET case TARGET-15-SJMPAL040032, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 0.4 years (135 days).
Specimen TARGET-15-SJMPAL040032-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c8e81c4d-766e-4014-835a-ef1a5cea73cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL040032-14A.1 (Bone Marrow Normal), aliquot TARGET-15-SJMPAL040032-14A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fcc72064-cfac-49f2-b3fc-427c9469ad93

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GPS1 | c.537C>A p.S179R | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.717); catalogued as COSV57647803; called by muse, mutect2
- OR1L1 | c.1063C>A p.H355N (on ENST00000373686; = p.H305N on NM_001005236.3) | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
